Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7734, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7734-01A (Primary Tumor).

[page 1 of 4]
Result
Narrative

SURGICAL PATHOLOGY REPORT

Pre-Operative/Clinical History
Right renal mass

Specimen(s) Received
A: RIGHT KIDNEY MASS

Gross Description
The specimen is received fresh from the OR labeled right kidney mass:

Specimen type/procedure: Partial nephrectomy.

Laterality: Right.

Description of specimen: The specimen consists of a 25 gm, 5.0 x 4.0 x 3.0 cm partial nephrectomy. There is a thin Gerota's fascia with multiple fibrous adhesions. The margins are inked as follows:

Margin of resection	Black
Gerota's fascia	Green.

Adrenal gland: Absent.

Tumor site: Cortical.

Tumor size: 4.0 x 3.5 x 3.5 cm.

Tumor description: Well-circumscribed, bright yellow, focally hemorrhagic solid mass.

[page 2 of 4]
Focality: Unifocal.

Extent of invasion: Tumor abuts Gerota's fascia and the parenchymal margin of resection.

Renal vessel involvement: Absent.

Renal hilum: Uninvolved.

Perinephric lymph nodes: Absent.

Renal parenchymal lesions: None identified.

Other: The mass encompasses approximately 90% of the specimen. The uninvolved parenchyma shows the usual corticomedullary junction.

Gross bench photographs are taken.

Sections:

(A1-A3) Mass and closest parenchymal margins of resection
(A4, A5) Mass to include parenchymal margin and Gerota's fascia
(A6) Mass and surrounding uninvolved parenchyma
(A7) Uninvolved parenchyma.

Microscopic Description

Sections include kidney with a sharply circumscribed, partially encapsulated epithelial neoplasm. The neoplasm is characterized by a predominantly solid or tubular growth pattern with foci of micropapillary or papilliform architecture. The predominant tumor cell is a small cuboidal cell with uniform, round, small bland nucleus and modest amounts of predominantly clear cytoplasm. There is a second cell population present in the lumina of the tubules. The luminal population consists of larger polygonal cells with eosinophilic cytoplasm and a single, slightly enlarged oval to reniform nucleus with granular chromatin and a small nucleolus. The latter cells form intraluminal poorly cohesive sheets. There are scattered foci of foamy macrophages within the interstitium of the tumor. Focally the tumor extends through its thin fibrous capsule and infiltrates into native renal parenchyma in a broad front. Focally tumor abuts on an inked parenchymal resection margin (black ink, A2). In the histologic sections convincing extrarenal extension into perinephric soft tissue is not identified.

A PAS stain is applied to sections of uninvolved nonneoplastic kidney (A7). It demonstrates very focal mild interstitial fibrosis and tubular atrophy with rare colocalized ischemic sclerotic glomeruli. The glomeruli are unremarkable. Neither crescents nor mesangial proliferation nor primary glomerulopathy is seen.

Summary of Pathologic Findings
Renal Carcinoma

Operative procedure: Laparoscopic robotically assisted right partial nephrectomy.

Tumor size: 4.0 x 3.5 x 3.5 cm.

Laterality and focality: Unilateral, right kidney

[page 3 of 4]
Histologic type: Papillary carcinoma, morphologic type I, predominant tubular growth pattern.

Sarcomatoid features: Absent.

Histologic grade: Furhman Grade 1-2.

Extent of invasion: No definite extrarenal extension identified. Tumor appears to be confined to kidney.

Lymph/vascular invasion: Absent.

Margins:

Partial nephrectomy/enucleation:

Renal capsule margin: Not involved.

Perinephric fat margin: Not involved.

Renal parenchyma margin: Focally involved.

Adrenal gland: Not submitted.

Regional lymph nodes: Not submitted.

Special studies: None.

PTNM stage: pT1a pNX PMX(not applicable).

Pathologic findings in nonneoplastic kidney: No significant pathologic findings identified. Focal minimal benign nephrosclerosis.

Diagnosis

RIGHT KIDNEY, RIGHT LAPAROSCOPIC PARTIAL NEPHRECTOMY:

PAPILLARY CARCINOMA, LOW GRADE.

NO EXTRARENAL TUMOR EXTENSION IDENTIFIED.

FOCAL INVOLVEMENT OF PARENCHYMAL MARGIN.

CPT Code(s)

A: 88329, 88307, 88313

Order

Order Authorizing
Providers Unknown, Provider

[page 4 of 4]
**Additional
Information**

Associated Reports

[View Encounter](#)

[Priority and Order Details](#)

[Collection Information](#)

Source: NCI Genomic Data Commons file d5a8b939-010b-42bc-8803-bffbe040ba04 (TCGA-A4-7734.BCB8E1A7-2BFE-4AE4-A17B-4DD2E219AC84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).